Somatic mutation profile of tumor specimen MMRF_1531_1_BM_CD138pos (aliquot MMRF_1531_1_BM_CD138pos_T1_KBS5U_L04119) from MMRF case MMRF_1531, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.0 years (23,360 days).
Specimen MMRF_1531_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ec94ea3-c871-4e44-b979-e591962ed632.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1531_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1531_1_PB_Whole_C2_KBS5U_L04125; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c9a17ac-3988-4a0b-9240-8eba9fe106bf

The open-access MAF lists 145 somatic variants for this specimen: 62 protein-altering or splice-affecting, 17 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, 3'UTR 33, Intron 17, Silent 17, RNA 7, 5'UTR 5, 3'Flank 3, Frame Shift Ins 2, Frame Shift Del 1, Splice Region 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>C p.Q61P | Missense Mutation (SNP) | VAF 54/150 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 55/149 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- CCKBR | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV58098769; called by muse, mutect2, varscan2
- CPAMD8 | c.850C>T p.R284W (on ENST00000651564; = p.R237W on NM_015692.5) | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs762012472, COSV52236808; called by muse, mutect2, varscan2
- CUEDC1 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs1385077512, COSV100804714; called by muse, mutect2, varscan2
- FLI1 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 28/588 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs375383556; called by muse, mutect2
- GPR4 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 63/353 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59916140; called by muse, mutect2, varscan2
- H4-16 | c.78T>A p.N26K | Missense Mutation (SNP) | VAF 197/366 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100797634; called by muse, mutect2, varscan2
- IGHV2-70 | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs138836314; called by muse, varscan2
- IGHV2-70D | c.230A>G p.D77G | Missense Mutation (SNP) | VAF 58/61 reads (95%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1466061529; called by muse, varscan2
- IGLL5 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 39/39 reads (100%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.112); catalogued as rs564743210, COSV73249743, COSV73250317, COSV73251309; called by muse, mutect2, varscan2
- IGLV1-44 | c.303G>C p.E101D | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.076); catalogued as rs769040748; called by muse, mutect2
- IGLV3-1 | c.160T>C p.Y54H | Missense Mutation (SNP) | VAF 59/60 reads (98%) | SIFT tolerated (0.05); PolyPhen benign (0.331); catalogued as rs61731690; called by muse, mutect2, varscan2
- IGLV5-45 | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.77); catalogued as rs192713801; called by muse, varscan2
- IGLV5-45 | c.286A>T p.N96Y | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs778587653; called by muse, varscan2
- ITFG1 | c.1606A>G p.I536V | Missense Mutation (SNP) | VAF 86/86 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs763027424; called by muse, mutect2, varscan2
- MAPK13 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as rs200916556, COSV52983921; called by muse, mutect2
- MPDZ | c.2209G>A p.G737S | Missense Mutation (SNP) | VAF 69/235 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs73406290; called by muse, mutect2, varscan2
- MS4A5 | c.436A>G p.I146V | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.09); catalogued as COSV55742780; called by muse, mutect2, varscan2
- OBSCN | c.18559C>T p.R6187W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs753823310, COSV52839238; called by muse, mutect2, varscan2
- PATJ | c.3347C>T p.T1116M | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777907543, COSV57175105; called by muse, mutect2, varscan2
- PCDHA3 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as COSV63543574, COSV99061555; called by muse, mutect2, varscan2
- PLA2G4D | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 166/479 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV51821796; called by muse, mutect2, varscan2
- PLEC | c.6574G>A p.A2192T (on ENST00000322810 / NM_201380.4; = p.A2082T on NM_000445.5) | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.019); catalogued as rs942658065; called by muse, mutect2, varscan2
- PPEF1 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs939041358, COSV62996497; called by muse, mutect2
- RD3 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 116/146 reads (79%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.88); catalogued as rs750239049, COSV65362804; called by muse, mutect2, varscan2
- SUN3 | c.876dup p.C293Mfs*2 | Frame Shift Ins (INS) | VAF 14/122 reads (11%) | catalogued as rs1392509769; called by mutect2, varscan2
- TNFRSF11A | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.223); catalogued as COSV54023182; called by muse, mutect2, varscan2
- TRAM1L1 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 32/418 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.179); catalogued as rs762544664, COSV60292194; called by muse, mutect2
- TRH | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 107/461 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as rs138139186; called by muse, mutect2, varscan2
- TSPAN12 | c.571A>G p.K191E | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs754576787; called by muse, mutect2, varscan2
- WIPF3 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs201706623; called by muse, mutect2, varscan2
- ANKRD17 | c.5364G>T p.L1788F | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASB2 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 11/130 reads (8%) | called by muse, mutect2
- CARD18 | c.223C>A p.H75N | Missense Mutation (SNP) | VAF 305/639 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CHN1 | c.655T>C p.C219R | Missense Mutation (SNP) | VAF 225/492 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTRL | c.2236A>G p.K746E | Missense Mutation (SNP) | VAF 143/211 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- FCGBP | c.11610G>C p.E3870D | Missense Mutation (SNP) | VAF 151/466 reads (32%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- FUT11 | c.210G>C p.E70D | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HACE1 | c.1679A>C p.D560A | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- HECTD4 | c.8127T>A p.G2709= | Splice Region (SNP) | VAF 67/141 reads (48%) | called by muse, mutect2, varscan2
- IGHV1-69 | c.165G>T p.W55C | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- LCN15 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 86/255 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- LRRC63 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRTM4 | c.386T>C p.F129S | Missense Mutation (SNP) | VAF 116/242 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSBPL7 | c.1637C>T p.S546F | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); called by muse, mutect2
- PALMD | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH15 | c.4745A>G p.E1582G | Missense Mutation (SNP) | VAF 173/694 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- PLCB4 | c.3459+2T>C p.X1153_splice | Splice Site (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- PLK2 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- SAMD9 | c.764A>T p.D255V | Missense Mutation (SNP) | VAF 68/285 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCG3 | c.1381A>G p.I461V | Missense Mutation (SNP) | VAF 30/530 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- SETD5 | c.1061G>A p.C354Y | Missense Mutation (SNP) | VAF 74/356 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC16A2 | c.959C>A p.T320N | Missense Mutation (SNP) | VAF 66/68 reads (97%) | SIFT tolerated (0.25); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- STOM | c.613A>G p.R205G | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STXBP5L | c.2093dup p.N698Kfs*16 | Frame Shift Ins (INS) | VAF 39/171 reads (23%) | called by mutect2, pindel, varscan2
- TRBV7-1 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.596); called by muse, mutect2
- TRIM33 | c.2273del p.G758Efs*16 | Frame Shift Del (DEL) | VAF 38/352 reads (11%) | called by mutect2, pindel
- TRIO | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 168/527 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- USPL1 | c.2127A>T p.K709N | Missense Mutation (SNP) | VAF 75/154 reads (49%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- ZNF250 | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 48/606 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- ZNF471 | c.1700G>C p.G567A | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGAP12 | c.2175C>T p.V725= | Silent (SNP) | VAF 25/67 reads (37%) | called by muse, mutect2, varscan2
- CDH22 | c.339C>T p.D113= | Silent (SNP) | VAF 99/231 reads (43%) | catalogued as rs774411837, COSV64837003, COSV64839481; called by muse, mutect2, varscan2
- CFAP100 | c.384C>T p.R128= | Silent (SNP) | VAF 133/212 reads (63%) | catalogued as rs749059919; called by muse, mutect2, varscan2
- CNTN3 | c.1968G>A p.K656= | Silent (SNP) | VAF 60/302 reads (20%) | called by muse, mutect2, varscan2
- CTNNA2 | c.885C>T p.S295= | Silent (SNP) | VAF 66/143 reads (46%) | catalogued as COSV63569278; called by muse, mutect2, varscan2
- DACH2 | c.591G>A p.L197= | Silent (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- FASN | c.3921G>T p.L1307= | Silent (SNP) | VAF 29/56 reads (52%) | called by muse, mutect2, varscan2
- GALNT10 | c.1335C>T p.D445= | Silent (SNP) | VAF 37/144 reads (26%) | called by muse, mutect2, varscan2
- GIMAP5 | c.909C>A p.I303= | Silent (SNP) | VAF 97/472 reads (21%) | catalogued as COSV100500296; called by muse, mutect2, varscan2
- IGHV2-70D | c.231T>C p.D77= | Silent (SNP) | VAF 56/60 reads (93%) | called by muse, varscan2
- IGHV4-34 | c.150C>G p.V50= | Silent (SNP) | VAF 89/188 reads (47%) | catalogued as rs587738411; called by muse, mutect2, varscan2
- IGLV4-60 | c.336C>T p.Y112= | Silent (SNP) | VAF 86/167 reads (51%) | catalogued as rs1568964881; called by muse, mutect2, varscan2
- MEFV | c.597C>T p.A199= | Silent (SNP) | VAF 37/65 reads (57%) | called by muse, mutect2, varscan2
- NANP | c.612A>G p.K204= | Silent (SNP) | VAF 36/87 reads (41%) | called by muse, mutect2, varscan2
- PCDH17 | c.3072C>G p.A1024= | Silent (SNP) | VAF 105/237 reads (44%) | called by muse, mutect2, varscan2
- RLIM | c.807G>A p.V269= | Silent (SNP) | VAF 33/33 reads (100%) | called by muse, mutect2, varscan2
- TSHZ1 | c.1845C>T p.A615= (on ENST00000580243 / NM_001308210.2; = p.A570= on NM_005786.6) | Silent (SNP) | VAF 51/100 reads (51%) | catalogued as rs766284453, COSV100433551; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA9 | c.*1030C>T | 3'UTR (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- AC009093.8 | n.263C>A | RNA (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- AC024651.2 | chr15:97874356 T>G | 5'Flank (SNP) | VAF 19/55 reads (35%) | catalogued as rs958795736; called by muse, mutect2, varscan2
- BAIAP3 | c.325-25C>T | Intron (SNP) | VAF 60/124 reads (48%) | called by muse, mutect2, varscan2
- BCL2L13 | c.*1824G>A | 3'UTR (SNP) | VAF 7/118 reads (6%) | called by muse, mutect2
- BLK | c.1030-585C>T | Intron (SNP) | VAF 16/36 reads (44%) | catalogued as rs560813454; called by muse, mutect2, varscan2
- BNIP3P1 | n.720G>A | RNA (SNP) | VAF 130/310 reads (42%) | called by muse, mutect2, varscan2
- C6orf99 | n.1123A>C | RNA (SNP) | VAF 171/318 reads (54%) | called by muse, mutect2, varscan2
- CALML4 | c.305-27A>T | Intron (SNP) | VAF 158/525 reads (30%) | called by muse, mutect2, varscan2
- CCDC121 | c.*994del | 3'UTR (DEL) | VAF 28/74 reads (38%) | catalogued as rs1006350373, COSV53114096; called by mutect2, varscan2
- CDH7 | chr18:65883120 A>G | 3'Flank (SNP) | VAF 17/114 reads (15%) | called by muse, mutect2, varscan2
- CHP2 | c.*83G>T | 3'UTR (SNP) | VAF 46/348 reads (13%) | called by muse, mutect2, varscan2
- DAOA | c.*96C>G | 3'UTR (SNP) | VAF 189/407 reads (46%) | called by muse, mutect2, varscan2
- DLX2 | c.585+62G>A | Intron (SNP) | VAF 86/201 reads (43%) | catalogued as rs1438770144; called by muse, mutect2, varscan2
- DOCK5 | c.1049+588G>T | Intron (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- DPPA4 | c.*915G>T | 3'UTR (SNP) | VAF 15/141 reads (11%) | called by muse, mutect2, varscan2
- EFCAB11 | c.*778A>G | 3'UTR (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- ELF2P4 | n.464C>A | RNA (SNP) | VAF 37/165 reads (22%) | called by muse, mutect2, varscan2
- EVX2 | c.*92C>A | 3'UTR (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- FGFR2 | c.*321A>T | 3'UTR (SNP) | VAF 34/436 reads (8%) | catalogued as COSV100336716; called by muse, mutect2
- GABRA2 | c.187+21311T>C | Intron (SNP) | VAF 113/228 reads (50%) | called by muse, mutect2, varscan2
- GABRA2 | c.187+17805T>C | Intron (SNP) | VAF 44/112 reads (39%) | called by muse, mutect2, varscan2
- GLI2 | c.*1705G>A | 3'UTR (SNP) | VAF 83/175 reads (47%) | catalogued as rs1035854222; called by muse, mutect2, varscan2
- GP5 | c.*804C>T | 3'UTR (SNP) | VAF 22/61 reads (36%) | catalogued as rs932414283; called by muse, mutect2, varscan2
- GRIN1 | c.2590-206C>T | Intron (SNP) | VAF 45/124 reads (36%) | catalogued as rs984534187; called by muse, mutect2, varscan2
- GTPBP8 | c.-2G>T | 5'UTR (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- H2BC11 | c.-44C>G | 5'UTR (SNP) | VAF 36/62 reads (58%) | called by muse, mutect2, varscan2
- IGLV1-44 | c.-40G>T | 5'UTR (SNP) | VAF 39/78 reads (50%) | called by muse, mutect2, varscan2
- IL1RAP | chr3:190656473 C>A | 3'Flank (SNP) | VAF 41/617 reads (7%) | called by muse, mutect2
- INHBA | c.*705A>G | 3'UTR (SNP) | VAF 59/102 reads (58%) | called by muse, varscan2
- INHBA | c.*666del | 3'UTR (DEL) | VAF 46/103 reads (45%) | called by pindel, varscan2
- ITSN1 | c.*3392G>C | 3'UTR (SNP) | VAF 62/133 reads (47%) | called by muse, mutect2, varscan2
- KALRN | c.4929+22985G>A | Intron (SNP) | VAF 65/210 reads (31%) | called by muse, mutect2, varscan2
- KLHDC7A | c.*2224C>A | 3'UTR (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
- LARGE1 | c.*129_*136del | 3'UTR (DEL) | VAF 22/88 reads (25%) | called by mutect2, pindel, varscan2
- LINC01546 | n.474T>C | RNA (SNP) | VAF 32/32 reads (100%) | called by muse, mutect2
- LINC02860 | n.1147T>A | RNA (SNP) | VAF 84/1208 reads (7%) | called by muse, mutect2
- LYRM7 | c.*2971C>A | 3'UTR (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- MASP1 | c.1303+5640G>T | Intron (SNP) | VAF 132/342 reads (39%) | catalogued as rs768033628, COSV56227923; called by muse, mutect2, varscan2
- NCAPD3 | c.2783-208C>T | Intron (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- OOSP3 | chr11:59898367 G>A | 3'Flank (SNP) | VAF 138/360 reads (38%) | called by muse, mutect2, varscan2
- PRUNE2 | c.*517T>C | 3'UTR (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- RAB3IP | c.*942T>C | 3'UTR (SNP) | VAF 41/112 reads (37%) | called by muse, mutect2, varscan2
- SH3BGRL2 | c.*2181C>T | 3'UTR (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- SHROOM3 | c.*3360T>C | 3'UTR (SNP) | VAF 47/92 reads (51%) | called by muse, mutect2, varscan2
- SLC39A8 | c.*244C>T | 3'UTR (SNP) | VAF 123/330 reads (37%) | catalogued as rs1433478939; called by muse, mutect2, varscan2
- SLCO3A1 | c.*2434G>C | 3'UTR (SNP) | VAF 6/196 reads (3%) | called by muse, mutect2
- SRRM3 | c.*1398G>A | 3'UTR (SNP) | VAF 68/192 reads (35%) | catalogued as rs542122591; called by muse, mutect2, varscan2
- SRSF10 | c.*6071G>C | 3'UTR (SNP) | VAF 10/118 reads (8%) | catalogued as rs910548108; called by muse, mutect2
- STAM2 | c.*224A>C | 3'UTR (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- STAMBPL1 | c.*701G>A | 3'UTR (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- STEAP4 | c.*3436C>A | 3'UTR (SNP) | VAF 18/111 reads (16%) | called by muse, mutect2, varscan2
- TCF4 | c.73-28A>G | Intron (SNP) | VAF 7/142 reads (5%) | called by muse, mutect2
- TEKT5 | c.565-46A>T | Intron (SNP) | VAF 46/112 reads (41%) | catalogued as rs1484696927; called by muse, mutect2, varscan2
- TMCO6 | c.499-106G>A | Intron (SNP) | VAF 18/396 reads (5%) | catalogued as rs1192650539; called by muse, mutect2
- TMEM163 | c.*725C>A | 3'UTR (SNP) | VAF 6/144 reads (4%) | catalogued as rs1484320415; called by muse, mutect2
- TNRC18P2 | n.1407G>T | RNA (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- TNRC6A | c.3695-45A>G | Intron (SNP) | VAF 31/59 reads (53%) | catalogued as rs576102536; called by muse, mutect2, varscan2
- TPO | c.2387-145del | Intron (DEL) | VAF 19/74 reads (26%) | called by mutect2, pindel
- TRAK2 | c.*3237C>T | 3'UTR (SNP) | VAF 19/65 reads (29%) | catalogued as rs1364186080; called by muse, mutect2, varscan2
- TRAV8-6 | c.-8G>A | 5'UTR (SNP) | VAF 30/64 reads (47%) | catalogued as rs914747432; called by muse, mutect2, varscan2
- TRPV6 | c.-39G>A | 5'UTR (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- UPB1 | c.364+867G>T | Intron (SNP) | VAF 74/157 reads (47%) | called by muse, mutect2, varscan2
- ZNF148 | c.*3189A>G | 3'UTR (SNP) | VAF 188/279 reads (67%) | called by muse, mutect2, varscan2
- ZNF772 | c.*2441_*2444del | 3'UTR (DEL) | VAF 58/212 reads (27%) | catalogued as rs1179255928; called by pindel, varscan2
- ZNF891 | c.*2011A>C | 3'UTR (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
